MMRF case MMRF_1605 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/8915f90c-b49a-4695-9fec-2f58150235c6

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 47 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 47.5 years (17,365 days); ISS stage: II; Days to last known disease status: 1,265 days (3.5 years); Days to last follow up: 1,265 days (3.5 years).
   Treatment given: Therapeutic agents: Bortezomib + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 176 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 113 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 114 days; Days to treatment end: 176 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 252 days; Days to treatment end: 252 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 383 days (1.0 years); Days to treatment end: 453 days (1.2 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 383 days (1.0 years); Days to treatment end: 494 days (1.4 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 383 days (1.0 years); Days to treatment end: 525 days (1.4 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 495 days (1.4 years); Days to treatment end: 525 days (1.4 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 523 days (1.4 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 579 days (1.6 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,265.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -9 (ECOG 0): M Protein 2.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 116 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.61 mg/dL; Immunoglobulin G 7.03 g/L; Immunoglobulin A 31 g/L; Immunoglobulin M 0.32 g/L; Beta 2 Microglobulin 3.07 µg/mL; Lactate Dehydrogenase 2.53 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 263 ×10⁹/L; Creatinine 104 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.23 mmol/L; Albumin 33 g/L; Total Protein 8.1 g/dL; Glucose 10.9 mmol/L; C-Reactive Protein 0.074 mg/dL.
- Day 89 (ECOG 1): M Protein 1.3 g/dL; Immunoglobulin G 8.51 g/L; Immunoglobulin A 6.43 g/L; Immunoglobulin M 0.89 g/L; Hemoglobin 6.76 mmol/L; Leukocytes 7.6 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 226 ×10⁹/L; Creatinine 108 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.13 mmol/L; Albumin 34 g/L; Total Protein 6.7 g/dL; Glucose 19.9 mmol/L.
- Day 158 (ECOG 1): Immunoglobulin G 11.9 g/L; Immunoglobulin A 7.14 g/L; Immunoglobulin M 0.92 g/L; Hemoglobin 6.76 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 197 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.13 mmol/L; Albumin 35 g/L; Total Protein 7.2 g/dL; Glucose 10 mmol/L.
- Day 279 (ECOG 0): M Protein 1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 21.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.37 mg/dL; Immunoglobulin G 12.7 g/L; Immunoglobulin A 6.79 g/L; Immunoglobulin M 0.96 g/L; Hemoglobin 6.88 mmol/L; Leukocytes 8.5 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 357 ×10⁹/L; Creatinine 157 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.3 mmol/L; Albumin 35 g/L; Total Protein 7.3 g/dL; Glucose 17 mmol/L.
- Day 362 (ECOG 0): M Protein 0.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.34 mg/dL; Immunoglobulin G 14.1 g/L; Immunoglobulin A 5.24 g/L; Immunoglobulin M 0.56 g/L; Hemoglobin 7.81 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 270 ×10⁹/L; Creatinine 102 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.25 mmol/L; Albumin 42 g/L; Total Protein 8 g/dL; Glucose 9.08 mmol/L.
- Day 439 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.97 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.17 mg/dL; Immunoglobulin G 10.5 g/L; Immunoglobulin A 3.9 g/L; Immunoglobulin M 0.98 g/L; Hemoglobin 7.32 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 112 ×10⁹/L; Creatinine 169 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 1.98 mmol/L; Albumin 35 g/L; Total Protein 7.1 g/dL; Glucose 22.9 mmol/L.
- Day 538 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 17.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.26 mg/dL; Immunoglobulin G 16.1 g/L; Immunoglobulin A 4.16 g/L; Immunoglobulin M 1.4 g/L; Hemoglobin 6.63 mmol/L; Leukocytes 6.6 ×10⁹/L; Platelets 182 ×10⁹/L; Creatinine 94.6 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.3 mmol/L; Albumin 35 g/L; Total Protein 8 g/dL; Glucose 9.96 mmol/L.
- Day 656 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 5.81 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.41 mg/dL; Immunoglobulin G 8.73 g/L; Immunoglobulin A 3.37 g/L; Immunoglobulin M 0.53 g/L; Hemoglobin 6.7 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 165 ×10⁹/L; Creatinine 116 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.15 mmol/L; Albumin 37 g/L; Total Protein 6.8 g/dL; Glucose 15.7 mmol/L.
- Day 726 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.08 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.38 mg/dL; Immunoglobulin G 8.38 g/L; Immunoglobulin A 3.3 g/L; Immunoglobulin M 0.59 g/L; Hemoglobin 6.14 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.44 ×10⁹/L; Platelets 175 ×10⁹/L; Creatinine 123 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.4 mmol/L; Albumin 40 g/L; Total Protein 7 g/dL; Glucose 16.6 mmol/L.
- Day 782 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.46 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.51 mg/dL; Immunoglobulin G 7.72 g/L; Immunoglobulin A 2.95 g/L; Immunoglobulin M 0.5 g/L; Hemoglobin 6.82 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 189 ×10⁹/L.
- Day 902 (ECOG 0): M Protein 0.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.65 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.03 mg/dL; Immunoglobulin G 8.45 g/L; Immunoglobulin A 2.91 g/L; Immunoglobulin M 0.46 g/L; Hemoglobin 7.32 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 243 ×10⁹/L.
- Day 985 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.52 mg/dL; Immunoglobulin G 7.59 g/L; Immunoglobulin A 2.87 g/L; Immunoglobulin M 0.43 g/L; Hemoglobin 6.39 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3.62 ×10⁹/L; Platelets 180 ×10⁹/L; Creatinine 126 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 6.7 g/dL; Glucose 11.1 mmol/L.
- Day 1,090 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.91 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.48 mg/dL; Hemoglobin 6.32 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.52 ×10⁹/L; Platelets 172 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.08 mmol/L; Total Protein 6 g/dL; Glucose 10.8 mmol/L.
- Day 1,175 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 2.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.81 mg/dL; Immunoglobulin G 9.08 g/L; Immunoglobulin A 2.64 g/L; Immunoglobulin M 0.7 g/L; Hemoglobin 6.26 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.14 ×10⁹/L; Platelets 205 ×10⁹/L; Creatinine 153 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 7.2 g/dL; Glucose 6.44 mmol/L.
- Day 1,261: Serum Free Immunoglobulin Light Chain, Kappa 4.27 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.94 mg/dL; Immunoglobulin G 8.06 g/L; Immunoglobulin A 2.64 g/L; Immunoglobulin M 0.49 g/L; Hemoglobin 6.2 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.65 ×10⁹/L; Platelets 142 ×10⁹/L; Creatinine 130 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.03 mmol/L; Albumin 39 g/L; Total Protein 6.9 g/dL; Glucose 17.4 mmol/L.

Other clinical attributes
- Day -9: Weight: 119 kg; Height: 172 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling.

Biospecimens (3 samples)
- Sample MMRF_1605_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -9 days.
- Sample MMRF_1605_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -9 days.
- Sample MMRF_1605_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 362 days.
